Somatic mutation profile of tumor specimen TARGET-10-PAPAMH-09A (aliquot TARGET-10-PAPAMH-09A-01D) from TARGET case TARGET-10-PAPAMH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,745 days).
Specimen TARGET-10-PAPAMH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de5cd789-7d76-4e00-8f7a-36c221e60909.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPAMH-10A (Blood Derived Normal), aliquot TARGET-10-PAPAMH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6360c549-09b4-4399-8125-e3098c62a299

The open-access MAF lists 20 somatic variants for this specimen: 12 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 7, In Frame Ins 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4505C>T p.P1502L | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555911573, COSV54326740, COSV54346809; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- SETD2 | c.4715+1G>C p.X1572_splice | Splice Site (SNP) | VAF 14/92 reads (15%) | hotspot (GDC flag); catalogued as rs1485723437, COSV57431126, COSV57439397; called by muse, mutect2, varscan2
- HYDIN | c.7531C>T p.R2511W | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774441724, COSV99992170; called by muse, mutect2, varscan2
- RPP40 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as rs779163622, COSV100124110; called by muse, mutect2, varscan2
- SLITRK6 | c.1778C>T p.T593M | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.212); catalogued as rs200638461, COSV101233307; called by muse, mutect2, varscan2
- STK31 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 2/9 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as rs754274194, COSV63455807; called by muse, mutect2
- CREBBP | c.4606_4607insGGG p.K1535_E1536insG | In Frame Ins (INS) | VAF 17/73 reads (23%) | called by mutect2, pindel, varscan2
- FAT4 | c.6934G>T p.A2312S | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.005); called by muse, mutect2
- FLT3 | c.2516_2517insGGGGGA p.S838_D839insEG | In Frame Ins (INS) | VAF 6/50 reads (12%) | called by pindel, varscan2
- OR4A16 | c.814T>C p.F272L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.097); called by muse, mutect2
- SH3D19 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2
- TGFBRAP1 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ANKRD30B | c.3621A>G p.G1207= | Silent (SNP) | VAF 23/143 reads (16%) | called by muse, mutect2, varscan2
- CSMD1 | c.8346C>T p.N2782= (on ENST00000520002; = p.N2781= on NM_033225.6) | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs761057412, COSV59380081; called by muse, mutect2, varscan2
- FAT1 | c.7959C>T p.G2653= | Silent (SNP) | VAF 60/100 reads (60%) | catalogued as rs768622107, COSV71676025; called by muse, mutect2, varscan2
- JAG1 | c.807G>A p.P269= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs753646278, COSV54761932; called by muse, mutect2, varscan2
- LPA | c.5010C>T p.A1670= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs762273541; called by muse, mutect2, varscan2
- NLGN2 | c.1359G>A p.A453= | Silent (SNP) | VAF 67/127 reads (53%) | catalogued as rs140045012; called by muse, mutect2, varscan2
- ROR1 | c.1401G>A p.E467= | Silent (SNP) | VAF 33/70 reads (47%) | catalogued as COSV100935367; called by muse, mutect2, varscan2
- NXF1 | chr11:62805442 T>C | 5'Flank (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
